Gene-level copy-number profile of tumor specimen TCGA-EY-A3QX-01A from TCGA case TCGA-EY-A3QX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 64.8 years (23,663 days).
Specimen TCGA-EY-A3QX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.93970094-a2ed-42f0-a74d-d42a728abfb0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EY-A3QX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2edfcbde-f84e-4eeb-95c0-c5ba35c7fbd5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 99; copy number 1: 19,574; copy number 2: 32,938; copy number 3: 6,037; copy number 4: 890; copy number 5: 90; copy number 6: 105; copy number 8: 14; copy number 9: 12; copy number 26: 21; copy number 30: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EY-A3QX-01A-11D-A227-01): tumor purity 0.83, ploidy 1.77, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 99 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:60,304,047–60,430,276, 2 genes: RNU6-806P, AC109486.1.
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–1): RB1.
- chr13:48,340,797–48,533,256, 4 genes (within-gene range 0–1): AL392048.1, LPAR6, Metazoa_SRP, RCBTB2.
- chr16:3,611,728–3,880,713, 6 genes (within-gene range 0–1): DNASE1, AC006111.2, TRAP1, AC006111.3, CREBBP, AC007151.1.
- chr16:34,266,041–35,912,516, 86 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 271 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,018,662–152,022,508, 1 gene, copy number 5: NBPF18P.
- chr3:121,431,427–121,660,927, 7 genes, copy number 5 (within-gene range 2–5): POLQ, RPL7AP11, ARGFX, FBXO40, HCLS1, RN7SL172P, RNU4-62P.
- chr3:168,249,522–168,830,599, 1 gene, copy number 6 (within-gene range 3–6): EGFEM1P.
- chr3:168,551,854–170,454,733, 42 genes, copy number 6: MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11.
- chr3:170,423,103–170,423,162, 1 gene, copy number 6: MIR6828.
- chr6:11,173,452–11,862,970, 15 genes, copy number 6–8 (within-gene range 3–8): AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP, AL022724.1, ADTRP, AL022724.3, AL022724.2, AMD1P4.
- chr7:158,532,718–159,233,377, 14 genes, copy number 5: MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, AC004863.1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr8:127,289,817–127,482,139, 1 gene, copy number 26 (within-gene range 1–26): CASC8.
- chr8:127,322,183–128,564,679, 20 genes, copy number 26: POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr9:3,630,947–3,689,626, 2 genes, copy number 5: AL354977.2, AL354977.1.
- chr9:3,875,584–3,901,248, 2 genes, copy number 5: AL137071.1, GLIS3-AS1.
- chr12:55,954,105–56,163,496, 22 genes, copy number 5: PMEL, CDK2, AC025162.1, RAB5B, AC034102.1, SUOX, IKZF4, AC034102.8, AC034102.3, RPS26, ERBB3, AC034102.2, PA2G4, AC034102.4, RPL41, ESYT1, ZC3H10, AC034102.7, AC034102.6, AC034102.5, MYL6B, MYL6.
- chr17:29,560,547–29,707,090, 1 gene, copy number 9 (within-gene range 3–9): ABHD15-AS1.
- chr17:29,589,769–29,614,761, 1 gene, copy number 9 (within-gene range 3–9): ANKRD13B.
- chr17:29,614,756–29,930,276, 10 genes, copy number 9 (within-gene range 1–9): CORO6, AC104564.2, SSH2, AC104564.1, RNU6-920P, AC104564.5, RPL21P123, AC023389.1, AC023389.2, SNORA70.
- chr17:39,461,486–40,061,215, 29 genes, copy number 30 (within-gene range 1–30): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124.
- chr20:31,440,632–31,723,989, 17 genes, copy number 5 (within-gene range 2–5): DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON.
- chr21:28,013,363–28,228,667, 3 genes, copy number 5: LINC00314, LINC01697, LINC01695.
- chr21:44,497,893–44,711,572, 1 gene, copy number 6 (within-gene range 2–6): TSPEAR.
- chr21:44,573,724–46,005,050, 59 genes, copy number 6: KRTAP10-4, KRTAP10-5, KRTAP10-6, KRTAP10-7, KRTAP10-8, KRTAP10-9, KRTAP10-10, KRTAP10-11, KRTAP12-4, KRTAP12-3, KRTAP12-2, IMMTP1, KRTAP12-1, KRTAP12-6P, KRTAP10-12, KRTAP10-13P, UBE2G2, LINC01424, SUMO3, PTTG1IP, ITGB2, ITGB2-AS1, AL844908.2, LINC01547, AL844908.1, FAM207A, AP001505.1, LINC00163, LINC00165, PICSAR, SSR4P1, ADARB1, AL133499.1, LINC00334, POFUT2, LINC00205, BX322557.2, LINC00315, BX322557.1, LINC00316, MTCO1P3, BX322559.1, BX322562.1, COL18A1, COL18A1-AS2, COL18A1-AS1, MIR6815, SLC19A1, LINC01694, AL133493.1, AL133493.2, PCBP3, AL133492.1, PCBP3-AS1, AJ011931.2, AJ011931.1, AJ239328.1, AJ011932.1, COL6A1.
- chr22:37,943,050–38,398,522, 22 genes, copy number 5 (within-gene range 2–5): C22orf23, AL031587.3, POLR2F, MIR6820, SOX10, MIR4534, AL031587.1, AL031587.4, PICK1, AL031587.2, SLC16A8, BAIAP2L2, AL022322.1, PLA2G6, AL022322.2, MAFF, TMEM184B, AL020993.1, RN7SL704P, Metazoa_SRP, CSNK1E, TPTEP2-CSNK1E.

Autosomal genes at a single copy (total copy number 1): 19,574. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
